Somatic mutation profile of tumor specimen TCGA-EE-A2MU-06A (aliquot TCGA-EE-A2MU-06A-21D-A196-08) from TCGA case TCGA-EE-A2MU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 75.8 years (27,688 days).
Specimen TCGA-EE-A2MU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6998a63d-a2bb-48d2-929e-89035956702c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MU-10A (Blood Derived Normal), aliquot TCGA-EE-A2MU-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/899a3342-877d-41f0-8b54-632624c5d533

The open-access MAF lists 772 somatic variants for this specimen: 503 protein-altering or splice-affecting, 252 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 452, Silent 252, Nonsense Mutation 35, Splice Site 7, Intron 6, 3'UTR 4, 5'Flank 3, Translation Start Site 3, Splice Region 3, RNA 2, 5'UTR 2, Frame Shift Ins 2.

Variants (750 of 772; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516792, CM071852, CM073191, COSV61068422, COSV61068985, COSV61070219; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 32/170 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- ABCB11 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV55587917; called by muse, mutect2, varscan2
- ABCC11 | c.2695C>T p.L899F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1200447326, COSV62325945; called by muse, mutect2, varscan2
- ABCC12 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs777462499, COSV60913232, COSV60918352; called by muse, mutect2, varscan2
- ABCC9 | c.1569G>A p.M523I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV53986465; called by mutect2, varscan2
- ABCC9 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53973161, COSV53987533; called by muse, mutect2, varscan2
- ABI1 | c.109T>C p.Y37H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs757934286, COSV61020324; called by muse, mutect2, varscan2
- ABI3BP | c.713G>A p.R238K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1408844193, COSV52548056, COSV52549099; called by muse, mutect2, varscan2
- AC008397.2 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV53209818; called by muse, mutect2, varscan2
- AC107959.5 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV63512326; called by muse, mutect2, varscan2
- AC126283.2 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as rs765956155, CM161604, COSV67099982; called by muse, mutect2, varscan2
- ACTG1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59510056; called by muse, mutect2, varscan2
- ADAM18 | c.1771G>A p.G591R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.105); catalogued as COSV55855324, COSV99696032; called by muse, mutect2, varscan2
- ADAM21 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV50810120; called by muse, mutect2, varscan2
- ADAM22 | c.1393-2A>G p.X465_splice | Splice Site (SNP) | VAF 7/65 reads (11%) | catalogued as COSV55990805; called by muse, mutect2, varscan2
- ADAM28 | c.1725G>A p.W575* | Nonsense Mutation (SNP) | VAF 16/157 reads (10%) | catalogued as COSV56105595; called by muse, mutect2, varscan2
- ADAMTS14 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.49); catalogued as rs768901348, COSV64606576; called by mutect2, varscan2
- ADAMTS19 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV50799572; called by muse, mutect2, varscan2
- ADGRG4 | c.4652C>T p.P1551L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV54965861; called by muse, mutect2, varscan2
- ADGRG4 | c.7843G>A p.E2615K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV54966929; called by muse, mutect2, varscan2
- AGAP4 | c.1970G>A p.G657D | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71165165; called by muse, mutect2, varscan2
- AGL | c.3052C>T p.L1018F | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV54058892; called by muse, mutect2, varscan2
- AGRN | c.3587C>T p.P1196L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV65072391; called by muse, mutect2, varscan2
- AIPL1 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as rs1329526327, COSV51509030; called by muse, mutect2, varscan2
- AKAP14 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100538264, COSV57630143, COSV57631417; called by muse, mutect2, varscan2
- AKAP3 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV57420745; called by muse, mutect2
- AKAP9 | c.3807A>T p.K1269N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs781687037, COSV62358190; called by muse, mutect2, varscan2
- AKNA | c.3808C>T p.Q1270* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV56340408; called by muse, mutect2, varscan2
- ALDH1A2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51079346; called by muse, mutect2, varscan2
- ALDH1L1 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as rs370745999; called by muse, mutect2, varscan2
- ALPK2 | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs1343132509, COSV64495041; called by muse, mutect2, varscan2
- AMPH | c.2023C>T p.Q675* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as rs760445860, COSV57751070; called by muse, mutect2, varscan2
- ANKEF1 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV65693748; called by muse, mutect2, varscan2
- ANKRD34A | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV60162092; called by muse, mutect2, varscan2
- ANKS4B | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV61140337; called by muse, mutect2
- APOL3 | c.415G>A p.E139K (on ENST00000349314 / NM_145640.2; = p.E68K on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs773979990, COSV62579095; called by muse, mutect2, varscan2
- ARHGAP29 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV53117108; called by muse, mutect2, varscan2
- ARHGEF17 | c.2753T>C p.I918T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV55238282; called by muse, mutect2, varscan2
- ARIH2 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV62706403; called by muse, mutect2, varscan2
- ARL9 | c.692A>G p.K231R (on ENST00000640821 / NM_001363794.2; = p.K89R on NM_206919.2) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.396); catalogued as rs201807967; called by muse, mutect2, varscan2
- ASH1L | c.1877G>T p.C626F | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV100853533; called by muse, mutect2, varscan2
- ASXL3 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV52473865, COSV52479896; called by muse, mutect2
- ATP13A5 | c.2151G>A p.M717I | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs267599736, COSV60866095; called by muse, mutect2, varscan2
- B3GALNT1 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.798); catalogued as COSV57581233; called by muse, mutect2, varscan2
- BCL9L | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52686185; called by muse, mutect2, varscan2
- BEST3 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV58305814; called by muse, mutect2, varscan2
- BMP10 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs767045695, COSV54897254; called by muse, mutect2, varscan2
- BPIFB1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV53605949; called by muse, mutect2, varscan2
- BRD4 | c.3644C>T p.S1215F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99651121; called by muse, mutect2
- BTBD8 | c.587T>A p.L196* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV61547799; called by muse, mutect2, varscan2
- C10orf120 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.919); catalogued as rs1348200874, COSV61492672; called by muse, mutect2, varscan2
- C1QB | c.389T>A p.V130D | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV59246101; called by muse, mutect2
- C1QTNF9 | c.919G>T p.G307* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV59658236; called by muse, mutect2, varscan2
- C1S | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV61072372; called by muse, mutect2, varscan2
- C3 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV55581577; called by muse, mutect2, varscan2
- C5 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99798384, COSV99798712; called by muse, mutect2
- C6orf15 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV52540037, COSV99456721; called by muse, mutect2, varscan2
- CACNA2D3 | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55582910; called by muse, mutect2, varscan2
- CARD11 | c.2375C>T p.T792I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV62754297, COSV62757140; called by muse, mutect2, varscan2
- CCDC60 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.058); catalogued as COSV59550708; called by muse, mutect2, varscan2
- CCDC73 | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as rs926589203, COSV58795592; called by muse, mutect2, varscan2
- CCT8L2 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV63461818; called by muse, mutect2, varscan2
- CD163 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs748750295, COSV63133563; called by muse, mutect2, varscan2
- CD200R1L | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.321); catalogued as COSV68004402, COSV68004974; called by muse, mutect2
- CDCP1 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs1244269384, COSV56103871; called by muse, mutect2, varscan2
- CDHR2 | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV56145577; called by muse, mutect2, varscan2
- CEACAM6 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV99555676; called by muse, mutect2, varscan2
- CELA3B | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV61404060; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV55829814; called by muse, mutect2, varscan2
- CFAP61 | c.1483G>C p.D495H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as rs1366628887, COSV55647857; called by muse, mutect2
- CGNL1 | c.1988A>G p.E663G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV55575405; called by muse, mutect2, varscan2
- CHAF1A | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs761043231, COSV56671786; called by muse, mutect2, varscan2
- CHD5 | c.3144+1G>A p.X1048_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as COSV52425131; called by muse, mutect2, varscan2
- CHD6 | c.4232A>G p.K1411R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.042); catalogued as COSV64694568; called by muse, mutect2
- CHRNA3 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs140801923; called by muse, mutect2, varscan2
- CIBAR1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1347570390, COSV63898351; called by muse, mutect2, varscan2
- CLYBL | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.06); catalogued as COSV59229376; called by muse, mutect2, varscan2
- CMTR1 | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs1235667568, COSV65091775; called by muse, mutect2, varscan2
- CMYA5 | c.7267G>A p.D2423N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); catalogued as COSV71409563; called by muse, mutect2, varscan2
- CNKSR2 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV54266710; called by muse, mutect2, varscan2
- CNTNAP5 | c.2493T>G p.N831K | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV70512600; called by muse, mutect2
- COL12A1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100485766, COSV59408120; called by muse, mutect2, varscan2
- COL12A1 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.056); catalogued as COSV59408131; called by muse, mutect2, varscan2
- COL19A1 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV59566707, COSV59578320; called by muse, mutect2, varscan2
- COL4A4 | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100307446, COSV61636731; called by muse, mutect2, varscan2
- COL5A2 | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66415380; called by muse, mutect2, varscan2
- COLQ | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.543); catalogued as COSV67526089; called by muse, mutect2, varscan2
- CPO | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.714); catalogued as COSV55941567; called by muse, mutect2, varscan2
- CRLF3 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV60837472; called by muse, mutect2, varscan2
- CSF2RB | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.623); catalogued as rs1259507244, COSV53261049; called by muse, mutect2, varscan2
- CSMD1 | c.8132T>C p.F2711S (on ENST00000520002; = p.F2710S on NM_033225.6) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59384437; called by muse, mutect2, varscan2
- CSMD2 | c.3860G>A p.G1287E | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53964419; called by muse, mutect2, varscan2
- CUX1 | c.1556C>T p.A519V (on ENST00000437600 / NM_181500.4; = p.A521V on NM_001913.5) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV52946775; called by muse, mutect2, varscan2
- DAB1 | c.881C>T p.P294L (on ENST00000371231; = p.P261L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1206615214, COSV64698312; called by muse, mutect2
- DCC | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV59089282, COSV59136256; called by muse, mutect2, varscan2
- DCDC1 | c.3409G>A p.E1137K (on ENST00000597505 / NM_001367979.1; = p.E244K on NM_020869.3) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV60313035; called by muse, mutect2, varscan2
- DCLK1 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV55211780, COSV55216574, COSV99713109; called by muse, mutect2, varscan2
- DDX60L | c.2484A>C p.R828S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV52722127; called by muse, mutect2
- DENND4A | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV71266888; called by mutect2, varscan2
- DGKK | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.077); catalogued as COSV65709255, COSV65709450; called by muse, mutect2, varscan2
- DHX15 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV61029346; called by muse, mutect2, varscan2
- DHX30 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV62396727; called by muse, mutect2
- DISP3 | c.4064C>T p.S1355F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53837692; called by muse, mutect2, varscan2
- DNAH11 | c.6618A>C p.K2206N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60981987; called by muse, mutect2, varscan2
- DNAH5 | c.1459T>G p.F487V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.219); catalogued as COSV54237708; called by muse, mutect2, varscan2
- DNAH7 | c.9436G>A p.E3146K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56764859; called by muse, mutect2
- DNAJC5G | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV56081323; called by muse, mutect2, varscan2
- DNAJC6 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV54781879; called by muse, mutect2, varscan2
- DOP1A | c.3599C>T p.S1200F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV52718312; called by muse, mutect2, varscan2
- DPAGT1 | c.1186T>A p.S396T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV53830147; called by muse, mutect2, varscan2
- DSCAM | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs780963598, COSV68654933; called by muse, mutect2, varscan2
- DSTYK | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as COSV65688481; called by muse, mutect2, varscan2
- DYSF | c.5620C>T p.P1874S | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV50593636; called by muse, mutect2, varscan2
- EFCAB14 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as rs1399566659, COSV64238193; called by muse, mutect2
- EFHB | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 91/361 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.404); catalogued as rs754774266, COSV55544894, COSV55550633; called by muse, mutect2, varscan2
- EGFL8 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 40/298 reads (13%) | catalogued as rs781715335, COSV61248709; called by muse, mutect2, varscan2
- EHMT1 | c.3448A>T p.T1150S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.268); catalogued as COSV101509716; called by muse, mutect2
- EHMT1 | c.3449C>T p.T1150I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101509717; called by muse, mutect2
- EML5 | c.4654G>A p.G1552R (on ENST00000380664; = p.G1560R on NM_183387.3) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61342471; called by muse, mutect2
- ENPEP | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54457579; called by muse, mutect2, varscan2
- ENPP1 | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV62936398; called by muse, mutect2
- EPHA4 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as rs867613646, COSV56025551; called by muse, mutect2, varscan2
- EPHA8 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756576145, COSV51296296; called by muse, mutect2, varscan2
- ERAP2 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.012); catalogued as rs1316183926, COSV65941438; called by muse, mutect2, varscan2
- ERBB4 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61468579; called by muse, mutect2, varscan2
- EYA4 | c.971G>T p.G324V (on ENST00000531901 / NM_001301013.1; = p.X324_splice on NM_004100.5) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV62060974; called by muse, mutect2, varscan2
- FAAP100 | c.1246+2T>C p.X416_splice | Splice Site (SNP) | VAF 39/106 reads (37%) | catalogued as COSV59887724; called by muse, mutect2, varscan2
- FAM104A | c.268dup p.Q90Pfs*6 | Frame Shift Ins (INS) | VAF 42/116 reads (36%) | catalogued as rs769947396; called by mutect2, varscan2
- FAM135B | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50526880; called by muse, mutect2, varscan2
- FAM210A | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs778033376, COSV59186120; called by muse, mutect2, varscan2
- FAM71B | c.1348G>A p.G450S | Missense Mutation (SNP) | VAF 160/502 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV57231336; called by muse, mutect2, varscan2
- FAM83B | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60926957; called by muse, mutect2, varscan2
- FAM83B | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as COSV60918820, COSV60926963; called by muse, mutect2, varscan2
- FAM83C | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 24/148 reads (16%) | catalogued as COSV65584524; called by muse, mutect2, varscan2
- FBXO8 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 16/103 reads (16%) | catalogued as COSV67032309; called by muse, mutect2, varscan2
- FCRL5 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.804); catalogued as COSV62520432; called by muse, mutect2, varscan2
- FHIT | c.414A>C p.E138D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV59325346; called by muse, mutect2, varscan2
- FILIP1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.804); catalogued as rs547365892, COSV52724856, COSV52726213; called by muse, mutect2, varscan2
- FLG | c.7500G>T p.R2500S | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs573055090, COSV64249576; called by muse, mutect2, varscan2
- FLG | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs967493717, COSV64236931; called by muse, mutect2, varscan2
- FLG2 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV66173502; called by muse, mutect2, varscan2
- FLT1 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as COSV56743444; called by muse, mutect2, varscan2
- FLT3 | c.2978C>T p.S993L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as rs968020606, COSV54043383; called by muse, mutect2, varscan2
- FMO1 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61447889; called by muse, mutect2, varscan2
- FMO3 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63008641; called by muse, mutect2, varscan2
- FOXP3 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV66052041; called by muse, mutect2, varscan2
- FOXS1 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54068393; called by muse, mutect2, varscan2
- FPR2 | c.449G>A p.W150* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | catalogued as COSV60674483; called by muse, mutect2
- FREM2 | c.6376G>A p.D2126N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs143509403; called by mutect2, varscan2
- FRS3 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs376525287, COSV52487028; called by mutect2, varscan2
- FSTL4 | c.203A>C p.K68T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs765364239, COSV54786259; called by muse, varscan2
- GABRA1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50119752; called by muse, mutect2, varscan2
- GABRG1 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV54956622, COSV99777603; called by muse, mutect2, varscan2
- GABRP | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54665810; called by muse, mutect2, varscan2
- GALNT10 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301016919, COSV51734416; called by muse, varscan2
- GALNT17 | c.960C>T p.I320= | Splice Region (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100352575, COSV61192457; called by muse, mutect2, varscan2
- GASK1B | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.439); catalogued as COSV99647937; called by muse, mutect2, varscan2
- GASK1B | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as COSV99647938; called by muse, mutect2, varscan2
- GCM2 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1430276294, COSV65276594; called by muse, mutect2, varscan2
- GCN1 | c.6484A>C p.S2162R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs576789409, COSV56113444, COSV56114961; called by muse, varscan2
- GH2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60426144; called by muse, mutect2, varscan2
- GJA10 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65356315; called by muse, mutect2, varscan2
- GK2 | c.1524G>A p.M508I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV62626909; called by muse, mutect2, varscan2
- GLUD2 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV60153212; called by muse, mutect2, varscan2
- GLYATL2 | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54850348; called by muse, mutect2, varscan2
- GP2 | c.1102G>A p.E368K (on ENST00000381362 / NM_001007240.3; = p.E365K on NM_001502.4) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV56892940; called by muse, mutect2, varscan2
- GPC6 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV65507534; called by muse, mutect2, varscan2
- GPR141 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as rs867379731, COSV57731434, COSV57731776; called by muse, varscan2
- GPR142 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs370594794, COSV100170775; called by mutect2, varscan2
- GRAMD4 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV63032734; called by muse, mutect2
- GRIA2 | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV52390594; called by muse, mutect2, varscan2
- GRIN2A | c.4229C>T p.S1410L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as rs1555481986, COSV58057236; ClinVar: uncertain significance; called by muse, varscan2
- GRIN2B | c.3853C>T p.P1285S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.955); catalogued as COSV74207926; called by muse, mutect2, varscan2
- GRIP1 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV54028453; called by muse, mutect2, varscan2
- GSG1 | c.346G>A p.E116K (on ENST00000651961 / NM_001080555.4; = p.E103K on NM_031289.5) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV60973649; called by muse, mutect2, varscan2
- GTF3C5 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371028258; called by muse, mutect2, varscan2
- HABP2 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as rs1223507582, COSV63638002; called by muse, mutect2, varscan2
- HDAC9 | c.2048G>A p.R683Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs753279370, COSV67768006, COSV67776035; called by muse, mutect2, varscan2
- HEATR5A | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as COSV66345284; called by muse, mutect2, varscan2
- HERC4 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV53275439; called by muse, mutect2, varscan2
- HESX1 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.783); catalogued as COSV55843730; called by muse, mutect2, varscan2
- HGD | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52201533; called by muse, mutect2, varscan2
- HIVEP3 | c.3830C>T p.P1277L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV56023921; called by muse, mutect2, varscan2
- HLTF | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59503712; called by muse, mutect2, varscan2
- HMSD | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV68817120; called by muse, mutect2, varscan2
- HOXA3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs1205537984, COSV57828997; called by muse, varscan2
- HTRA1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV64565317; called by muse, mutect2, varscan2
- HTRA3 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs776712915, COSV56473429; called by muse, mutect2, varscan2
- HTT | c.2293C>T p.R765* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV61857058; called by muse, mutect2, varscan2
- IFNA10 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs752204712, COSV53330732; called by muse, mutect2, varscan2
- IFNA14 | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV66516483; called by muse, mutect2, varscan2
- INPP5F | c.1821G>A p.M607I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV62823858; called by muse, mutect2, varscan2
- INSR | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57173432; called by muse, mutect2, varscan2
- IRAG1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70213069; called by muse, mutect2, varscan2
- ISL1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV57935780; called by muse, varscan2
- ITGAX | c.2743C>T p.Q915* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV51651665; called by muse, mutect2, varscan2
- ITGAX | c.3137C>T p.T1046I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV51651678; called by muse, varscan2
- ITK | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 154/467 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs372181411; called by muse, mutect2, varscan2
- ITSN1 | c.4853A>G p.N1618S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV67157655; called by muse, mutect2, varscan2
- JHY | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV57080300; called by muse, mutect2, varscan2
- KCNAB1 | c.350C>T p.S117L (on ENST00000490337 / NM_172160.3; = p.S106L on NM_003471.3) | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as COSV56743109; called by muse, mutect2, varscan2
- KCNB2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs267601987, COSV73053051; called by muse, mutect2, varscan2
- KCNG1 | c.558C>A p.D186E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100857181, COSV65370498; called by muse, mutect2, varscan2
- KCNJ3 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV54538795, COSV54544877; called by muse, mutect2
- KCNK18 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs769564486, COSV57973331; called by muse, mutect2, varscan2
- KCNN3 | c.1774C>T p.R592W (on ENST00000618040 / NM_001204087.1; = p.R577W on NM_002249.6) | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55216437; called by muse, mutect2, varscan2
- KCNT2 | c.3127C>T p.L1043F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV54109511; called by muse, mutect2, varscan2
- KCNT2 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV54093604; called by muse, mutect2, varscan2
- KCNU1 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.44); catalogued as rs773221041, COSV67759076; called by muse, mutect2, varscan2
- KIAA0319 | c.3184G>A p.G1062R | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65501937; called by muse, mutect2, varscan2
- KIF5C | c.2504C>T p.S835F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs760077899, COSV68479817; called by muse, mutect2
- KMT5B | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1164268086, COSV58564146; called by muse, mutect2
- KRT38 | c.1020+1G>A p.X340_splice | Splice Site (SNP) | VAF 12/54 reads (22%) | catalogued as COSV55847701; called by muse, mutect2, varscan2
- KRTAP13-1 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as rs375659426; called by mutect2, varscan2
- LCT | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as COSV99919270; called by muse, mutect2, varscan2
- LDB2 | c.140A>C p.D47A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100452788, COSV58783077; called by muse, mutect2, varscan2
- LGALS9 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV100119501; called by muse, mutect2, varscan2
- LHCGR | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54291907; called by muse, mutect2, varscan2
- LONP2 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV53526318; called by muse, mutect2, varscan2
- LPA | c.4117C>T p.P1373S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.888); catalogued as COSV60302386; called by muse, mutect2, varscan2
- LPO | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs755945869, COSV51860981; called by mutect2, varscan2
- LRP1B | c.1037G>A p.G346E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753992414, COSV67275891; called by muse, mutect2, varscan2
- LRRC66 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV58636882, COSV58637159; called by muse, mutect2, varscan2
- LRRC7 | c.967G>A p.D323N (on ENST00000651989 / NM_001370785.2; = p.D290N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); catalogued as COSV50630598; called by muse, mutect2, varscan2
- LRRIQ3 | c.1770G>A p.M590I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100599072; called by muse, mutect2, varscan2
- LRRN2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65784730; called by muse, mutect2
- LRTM2 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV54566793; called by muse, varscan2
- LTBP1 | c.2902G>A p.G968R (on ENST00000404816 / NM_206943.4; = p.G642R on NM_000627.4) | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as rs761010050, COSV63198102; called by muse, mutect2, varscan2
- LY9 | c.1229C>G p.S410* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV54438070, COSV99626841; called by muse, varscan2
- MACROH2A1 | c.524C>T p.T175I (on ENST00000510038; = p.T174I on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.368); catalogued as COSV56898171; called by muse, mutect2, varscan2
- MAD1L1 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as rs765516978, COSV54249206; called by muse, mutect2, varscan2
- MAGEB16 | c.497T>G p.F166C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67873521; called by muse, mutect2, varscan2
- MAGI1 | c.2809T>A p.S937T (on ENST00000402939 / NM_001033057.2; = p.S965T on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.333); catalogued as COSV58345011; called by muse, mutect2
- MAN1C1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1222271712, COSV56048742; called by muse, mutect2, varscan2
- MAP3K12 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57236405; called by muse, mutect2
- MAP7 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs914123425, COSV63418630, COSV63420299; called by muse, mutect2, varscan2
- MAPK13 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as COSV52985108; called by muse, mutect2, varscan2
- MARK1 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV65071497; called by muse, mutect2, varscan2
- MASP1 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV61830945; called by muse, mutect2, varscan2
- MCHR2 | c.150del p.G51Afs*9 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as COSV56010258; called by mutect2, pindel
- MCTP2 | c.2615G>A p.R872Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs141407505; called by muse, mutect2, varscan2
- MDGA1 | c.2707G>A p.D903N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99777179; called by muse, mutect2, varscan2
- METTL14 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV66310645; called by muse, mutect2, varscan2
- METTL15 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760714023, COSV57724175; called by muse, mutect2, varscan2
- MGAM | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV71885044; called by muse, mutect2
- MLKL | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs1567598450, COSV58206667; called by muse, mutect2, varscan2
- MMP1 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as COSV59511147; called by muse, mutect2, varscan2
- MOCOS | c.2195C>T p.S732F | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54346869; called by muse, mutect2, varscan2
- MRE11 | c.1954G>A p.E652K (on ENST00000323929 / NM_005591.4; = p.E624K on NM_005590.4) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); catalogued as COSV60574068, COSV60580420; called by muse, mutect2, varscan2
- MROH2B | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 21/136 reads (15%) | catalogued as rs200958096, COSV68184773; called by muse, mutect2, varscan2
- MROH9 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV100882892, COSV63013357; called by muse, mutect2, varscan2
- MTMR8 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66396348; called by muse, mutect2
- MUC17 | c.11561C>T p.S3854L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs868699134, COSV60283652, COSV60289553; called by muse, mutect2, varscan2
- MUC6 | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV70150413; called by muse, mutect2, varscan2
- MYCBP2 | c.13855G>T p.V4619F (on ENST00000357337; = p.V4657F on NM_015057.5) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as COSV62039439; called by muse, mutect2, varscan2
- MYF5 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57356644; called by muse, mutect2, varscan2
- MYH1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV56848008, COSV56855146; called by muse, mutect2, varscan2
- MYH2 | c.4759G>A p.E1587K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV55448636, COSV99820366; called by muse, mutect2, varscan2
- MYH2 | c.2239G>A p.A747T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV55448645; called by muse, mutect2, varscan2
- MYLK | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 83/309 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751096220, COSV60622995; called by muse, mutect2, varscan2
- MYO1A | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55657423; called by muse, mutect2, varscan2
- N4BP2 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1194614436, COSV54699625, COSV54702803; called by muse, mutect2, varscan2
- NASP | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63114809; called by muse, mutect2, varscan2
- NCEH1 | c.598C>T p.H200Y (on ENST00000538775; = p.H160Y on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56437731; called by muse, mutect2, varscan2
- NCOA5 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV99275823; called by muse, mutect2, varscan2
- NCOA5 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV99275356, COSV99275829; called by muse, mutect2, varscan2
- NEB | c.12349G>A p.E4117K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51460662; called by muse, mutect2, varscan2
- NEB | c.8109G>A p.M2703I | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV51460683; called by muse, mutect2, varscan2
- NLRC4 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100707364, COSV61594142; called by muse, mutect2, varscan2
- NLRP2 | c.2239C>T p.L747F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV54760435, COSV54760509; called by muse, mutect2, varscan2
- NLRP2 | c.2746G>A p.D916N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs374020777; called by muse, mutect2, varscan2
- NOX3 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV50163846; called by muse, mutect2, varscan2
- NR1I3 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63469403; called by muse, mutect2, varscan2
- NRAS | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV54742392, COSV54742468; called by muse, mutect2, varscan2
- NRG2 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.449); catalogued as COSV56840708; called by muse, mutect2, varscan2
- NRP1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55177679; called by muse, mutect2, varscan2
- NT5DC3 | c.1371G>A p.W457* | Nonsense Mutation (SNP) | VAF 12/92 reads (13%) | catalogued as COSV67322926; called by muse, mutect2, varscan2
- NUP210 | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs769477827, COSV54414200; called by muse, mutect2, varscan2
- NWD1 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60351916; called by muse, mutect2, varscan2
- OLFM3 | c.977G>A p.R326Q (on ENST00000338858 / NM_001288821.1; = p.R306Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1278883199, COSV58800476; called by muse, mutect2, varscan2
- OR10A5 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs773136547, COSV55055741; called by muse, mutect2, varscan2
- OR10J5 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58385072; called by mutect2, varscan2
- OR10T2 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57780222, COSV57781610; called by mutect2, varscan2
- OR11H6 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59645392; called by muse, mutect2, varscan2
- OR1C1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV101376285, COSV68715934; called by muse, mutect2, varscan2
- OR2A5 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV101278802; called by muse, varscan2
- OR2A5 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV101278804; called by muse, varscan2
- OR2C3 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs762142020, COSV63576357; called by mutect2, varscan2
- OR2F2 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV68833357; called by muse, mutect2, varscan2
- OR2L13 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as COSV63553592, COSV63561108; called by muse, mutect2, varscan2
- OR2M4 | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60707134; called by muse, mutect2, varscan2
- OR2T11 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV58185285; called by muse, mutect2, varscan2
- OR2T2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 19/400 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs1431425376, COSV61617845; called by muse, mutect2
- OR4P4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs868535274, COSV58923624; called by muse, mutect2, varscan2
- OR51F2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs773522707, COSV59063713, COSV59065439; called by muse, mutect2, varscan2
- OR51I2 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs576821557, COSV58300328; called by muse, mutect2, varscan2
- OR56A3 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61569731, COSV61570064; called by muse, mutect2, varscan2
- OR56A3 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61570070; called by muse, mutect2, varscan2
- OR5H15 | c.925+2T>A p.X309_splice (on ENST00000383696; = p.V309= on NM_001005515.1) | Splice Site (SNP) | VAF 16/37 reads (43%) | catalogued as COSV62949064; called by muse, mutect2, varscan2
- OR6A2 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs373299055; called by muse, mutect2, varscan2
- OR8I2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs561919245, COSV56169726, COSV56170425; called by muse, mutect2, varscan2
- OTOGL | c.3818C>T p.S1273F (on ENST00000547103; = p.S1264F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72005875; called by muse, mutect2, varscan2
- P2RY2 | c.1028G>A p.R343K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60777810; called by muse, mutect2, varscan2
- PAIP1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs149920694; called by muse, mutect2, varscan2
- PAK5 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62038159; called by muse, mutect2, varscan2
- PAN2 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV57756164; called by muse, mutect2
- PAPPA2 | c.3623C>T p.S1208F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.115); catalogued as rs267598192, COSV62792202; called by muse, mutect2, varscan2
- PCDHA12 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.364); catalogued as rs1554168093, COSV56475083; called by muse, mutect2, varscan2
- PCDHB3 | c.2221G>A p.G741S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.326); catalogued as COSV50611441; called by muse, mutect2, varscan2
- PCLO | c.11792T>A p.V3931E | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.9); catalogued as COSV61666899; called by muse, mutect2
- PCLO | c.8236G>A p.D2746N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs867757008, COSV61616448, COSV61625308; called by muse, mutect2, varscan2
- PCLO | c.4783G>A p.E1595K | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.187); catalogued as COSV61617770; called by muse, mutect2, varscan2
- PCNX2 | c.3946C>T p.H1316Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs754079857, COSV50836927; called by muse, mutect2, varscan2
- PCSK1 | c.1221G>T p.M407I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV60737588; called by muse, mutect2, varscan2
- PCSK6 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as rs1417112637, COSV60170876; called by muse, mutect2, varscan2
- PDE3B | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56390821; called by muse, mutect2, varscan2
- PDE4A | c.1010G>A p.G337E (on ENST00000380702 / NM_001111307.2; = p.G98E on NM_006202.3) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53362906; called by muse, mutect2, varscan2
- PDPK1 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV51913352, COSV51914642; called by muse, mutect2, varscan2
- PECR | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV54735936; called by muse, mutect2, varscan2
- PEG3 | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as COSV55648037; called by muse, mutect2
- PEG3 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV55648066; called by muse, mutect2, varscan2
- PHKB | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV54534351; called by muse, mutect2
- PIK3C2B | c.4538C>T p.S1513F | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65814350; called by muse, mutect2, varscan2
- PIK3CG | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.214); catalogued as rs142342118; called by muse, mutect2, varscan2
- PIK3R2 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV55847552, COSV55850329; called by muse, mutect2, varscan2
- PKD1L1 | c.7691C>T p.S2564F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV51845164; called by muse, mutect2, varscan2
- PKD1L1 | c.4702G>A p.D1568N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV56962820; called by muse, mutect2, varscan2
- PKD1L1 | c.4304C>T p.S1435L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.289); catalogued as rs371773823; called by muse, mutect2, varscan2
- PLCB4 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53802111; called by muse, mutect2, varscan2
- PLCE1 | c.3796G>A p.D1266N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV53353161, COSV53372635; called by muse, mutect2, varscan2
- PLEKHA7 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV63051189; called by muse, mutect2, varscan2
- PLEKHH2 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1160520202, COSV56761404; called by muse, mutect2, varscan2
- PLXNC1 | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV51571014; called by muse, mutect2, varscan2
- PMFBP1 | c.1761G>A p.M587I (on ENST00000537465; = p.M582I on NM_031293.3) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV52822118; called by muse, mutect2, varscan2
- POU4F3 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV57945020, COSV57945463; called by muse, mutect2, varscan2
- PPARGC1A | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.674); catalogued as COSV53533758; called by muse, mutect2, varscan2
- PPIP5K2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781989396, COSV58609994; called by muse, mutect2, varscan2
- PPP1R9A | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV56911314; called by muse, mutect2, varscan2
- PRAMEF2 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.502); catalogued as rs140567467; called by muse, mutect2, varscan2
- PREX2 | c.1645C>T p.L549F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55766291; called by muse, mutect2, varscan2
- PRKAA2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1417490638, COSV64806729; called by muse, mutect2, varscan2
- PRKCB | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.216); catalogued as COSV57802110; called by muse, mutect2, varscan2
- PRKN | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as CM0911479, COSV58279819; called by muse, mutect2, varscan2
- PSG3 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs868010416, COSV59505037; called by muse, mutect2, varscan2
- PSG6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV51830662, COSV99413742; called by muse, mutect2
- PSMA1 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67166208; called by muse, mutect2, varscan2
- PTPN5 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62125373; called by muse, mutect2, varscan2
- PTPRK | c.2902G>A p.D968N (on ENST00000368215 / NM_001291984.2; = p.D969N on NM_002844.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63907420; called by muse, mutect2, varscan2
- PTPRT | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62021999; called by muse, mutect2, varscan2
- PTPRT | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as rs868489194, COSV61963246; called by muse, mutect2, varscan2
- PURG | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV53299413; called by muse, mutect2, varscan2
- PVR | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 48/359 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs1264431695, COSV51824803; called by muse, mutect2, varscan2
- RAB19 | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52046105; called by muse, mutect2, varscan2
- RAB27A | c.273T>G p.D91E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.631); catalogued as COSV61018084; called by muse, mutect2, varscan2
- RAB3GAP1 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1371556132, COSV51488824, COSV99920435; called by muse, mutect2, varscan2
- RBM6 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1207352915, COSV56488146; called by muse, mutect2
- RCOR1 | c.498G>A p.Q166= | Splice Region (SNP) | VAF 5/64 reads (8%) | catalogued as COSV51769317, COSV51772588; called by muse, mutect2
- RDH16 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV62458816; called by muse, mutect2, varscan2
- RELCH | c.3598C>T p.Q1200* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | catalogued as COSV56892470; called by muse, mutect2, varscan2
- RENBP | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100892454; called by muse, mutect2, varscan2
- REPS2 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.136); catalogued as COSV58188349; called by muse, mutect2, varscan2
- RERE | c.4405C>T p.P1469S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61950987; called by muse, mutect2
- RPH3A | c.1121C>T p.P374L (on ENST00000389385 / NM_001143854.2; = p.P370L on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs541230100, COSV66993050; called by mutect2, varscan2
- RPL13A | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV52620918; called by muse, mutect2, varscan2
- RPS6KA5 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.85); catalogued as COSV100003473, COSV56225810; called by muse, mutect2, varscan2
- RTN2 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV55596094; called by muse, mutect2, varscan2
- RYR3 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770423247, COSV66808881; called by mutect2, varscan2
- SAMD9L | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV59081909; called by muse, mutect2, varscan2
- SCG5 | c.79T>C p.Y27H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100276879; called by muse, mutect2, varscan2
- SCN1A | c.3218T>G p.L1073R (on ENST00000303395 / NM_001202435.3; = p.L1062R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100323034, COSV57688201; called by muse, mutect2, varscan2
- SCN7A | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV69272954; called by muse, mutect2, varscan2
- SCN9A | c.4814C>T p.S1605F (on ENST00000303354; = p.S1594F on NM_002977.3) | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57624665; called by muse, mutect2
- SEMA4G | c.1361G>A p.W454* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV52972288; called by muse, mutect2, varscan2
- SH3BP5L | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV63540013; called by muse, mutect2, varscan2
- SH3RF2 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV63040834; called by muse, mutect2, varscan2
- SHANK2 | c.3325G>A p.D1109N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1312804628, COSV53584119; called by muse, mutect2, varscan2
- SIGLEC7 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs759671422, COSV58315054; called by muse, mutect2, varscan2
- SIGLEC7 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58317937; called by muse, mutect2, varscan2
- SIX4 | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs756235258, COSV53671234; called by muse, mutect2, varscan2
- SLC15A1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64733728; called by muse, mutect2, varscan2
- SLC22A6 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV64561136; called by muse, mutect2, varscan2
- SLC23A1 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV62297664; called by muse, mutect2
- SLC24A3 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.156); catalogued as COSV100041723, COSV60111523; called by muse, mutect2, varscan2
- SLC27A6 | c.1035G>A p.W345* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs762282269, COSV52487840; called by muse, mutect2, varscan2
- SLC28A1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54486209; called by muse, mutect2, varscan2
- SLC35F5 | c.617C>G p.P206R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV55520706; called by muse, mutect2, varscan2
- SLC5A7 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50905003; called by muse, mutect2, varscan2
- SLC6A9 | c.1883C>T p.A628V (on ENST00000360584 / NM_201649.4; = p.A574V on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.24); catalogued as COSV62212158; called by muse, mutect2, varscan2
- SLC9B1 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56469913, COSV56475587; called by muse, mutect2, varscan2
- SLC9B2 | c.1154T>C p.V385A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV60018750; called by muse, mutect2, varscan2
- SLCO6A1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as rs1345516298, COSV65805937; called by muse, mutect2, varscan2
- SLITRK5 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV61521999; called by muse, mutect2, varscan2
- SLITRK6 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1238316856, COSV68391732; called by muse, mutect2, varscan2
- SMC3 | c.2749C>T p.H917Y | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV62422412; called by muse, mutect2
- SMOC2 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.09); catalogued as COSV62444419; called by muse, mutect2, varscan2
- SMPD4 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs755218803, COSV60079083, COSV60081308; called by muse, mutect2, varscan2
- SNX7 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100069194, COSV100069300; called by muse, mutect2, varscan2
- SNX7 | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV100069303; called by muse, mutect2, varscan2
- SORL1 | c.4946G>A p.G1649E | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52762905; called by muse, mutect2, varscan2
- SPATA17 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146794589, COSV65122896; called by muse, mutect2
- SPATA31D1 | c.3811G>A p.E1271K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as COSV61193320; called by muse, mutect2, varscan2
- SPG11 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV55995571; called by muse, mutect2, varscan2
- SPHKAP | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1222721024, COSV60894645; called by muse, mutect2, varscan2
- SPOCD1 | c.3245G>A p.G1082E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.333); catalogued as COSV57100183; called by muse, mutect2, varscan2
- SPON1 | c.360A>C p.E120D | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV59968444; called by muse, mutect2
- SPRR3 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); catalogued as COSV54881477; called by muse, mutect2, varscan2
- ST14 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.076); catalogued as rs950464674, COSV99598978; called by muse, mutect2, varscan2
- SUSD1 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV62585476; called by muse, mutect2
- SV2A | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781926005, COSV64965949; called by muse, mutect2, varscan2
- SVEP1 | c.4285G>A p.D1429N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100239091, COSV57048202; called by muse, mutect2, varscan2
- SYTL1 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58874500; called by muse, mutect2, varscan2
- TAAR9 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV71512343; called by muse, mutect2, varscan2
- TAB2 | c.1477C>T p.H493Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as COSV53855469; called by muse, mutect2, varscan2
- TAF1L | c.5227G>A p.D1743N | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.388); catalogued as COSV54270380; called by muse, mutect2, varscan2
- TBC1D7 | c.666-1G>A p.X222_splice | Splice Site (SNP) | VAF 11/130 reads (8%) | catalogued as COSV58245071; called by muse, mutect2
- TBC1D9 | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV71308980; called by muse, mutect2, varscan2
- TCF4 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV61906537; called by muse, mutect2, varscan2
- TCHH | c.5420G>A p.R1807K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.208); catalogued as rs766653214, COSV64276203, COSV64277827; called by muse, mutect2, varscan2
- TCHHL1 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1310873245, COSV64287697; called by muse, mutect2, varscan2
- TCIRG1 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1300141877, COSV55837540; called by muse, mutect2, varscan2
- TCL1B | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV61552376; called by mutect2, varscan2
- TDRD1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52596328; called by muse, mutect2, varscan2
- TEC | c.1535+1G>A p.X512_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV67406503; called by muse, mutect2, varscan2
- TECPR2 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.115); catalogued as COSV63974320; called by muse, mutect2, varscan2
- TET1 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV65386175; called by muse, mutect2, varscan2
- TFAP4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52597990; called by muse, mutect2, varscan2
- THADA | c.3685C>T p.P1229S | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774972640, COSV57693481; called by muse, mutect2, varscan2
- THOC5 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as COSV63801194; called by muse, mutect2, varscan2
- THSD7B | c.3349C>T p.P1117S (on ENST00000272643; = p.P1115S on NM_001316349.2) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV55738693, COSV99758933; called by muse, mutect2, varscan2
- TLCD1 | c.266G>A p.C89Y | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52048890; called by muse, mutect2, varscan2
- TLL1 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.119); catalogued as rs150952504; called by mutect2, varscan2
- TMCC1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as COSV101282060; called by muse, mutect2, varscan2
- TMCC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV101282061; called by muse, mutect2, varscan2
- TMEM132B | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs764230525, COSV54770160; called by muse, mutect2, varscan2
- TMEM161A | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.793); catalogued as COSV50778062; called by muse, mutect2, varscan2
- TMEM62 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs906458103, COSV53042535, COSV53042977; called by muse, mutect2, varscan2
- TMEM67 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.42); catalogued as rs779483635, COSV60044569; called by muse, mutect2, varscan2
- TMPRSS13 | c.1672A>T p.M558L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV70627938; called by muse, mutect2, varscan2
- TNKS | c.1505T>C p.L502S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as COSV60066542; called by muse, mutect2
- TNN | c.3377G>A p.W1126* | Nonsense Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as COSV53435823, COSV99512880; called by muse, mutect2, varscan2
- TNRC6C | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV56953071; called by muse, mutect2, varscan2
- TNXB | c.3613C>A p.Q1205K (on ENST00000647633; = p.Q958K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.561); catalogued as COSV64489056; called by muse, mutect2, varscan2
- TOPBP1 | c.4168G>T p.V1390F | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV53441838; called by muse, mutect2
- TOX4 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99398470; called by muse, mutect2, varscan2
- TPR | c.4813C>T p.Q1605* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as COSV66605121; called by muse, mutect2, varscan2
- TRANK1 | c.7057G>A p.E2353K | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV57164351; called by muse, varscan2
- TRANK1 | c.1824C>A p.N608K | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as COSV57164412; called by muse, mutect2, varscan2
- TRAV10 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs866953660; called by muse, mutect2, varscan2
- TRHDE | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.116); catalogued as COSV53866572; called by muse, varscan2
- TRPM6 | c.2627G>A p.S876N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs761083300, COSV62522832; called by muse, mutect2, varscan2
- TRPM7 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57921639; called by muse, mutect2, varscan2
- TRPV5 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867533205, COSV54689960; called by muse, mutect2
- TSHZ2 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.205); catalogued as rs780372638, COSV61591621; called by mutect2, varscan2
- TSPAN12 | c.719T>C p.L240P | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56082034; called by muse, mutect2
- TSSK4 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55305211; called by muse, mutect2, varscan2
- TTN | c.56252G>A p.W18751* (on ENST00000591111; = p.W11327* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 34/144 reads (24%) | catalogued as COSV60354946; called by muse, mutect2, varscan2
- TTN | c.26937G>A p.E8979= (on ENST00000591111; = p.E8052= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 4/48 reads (8%) | catalogued as COSV60354985; called by muse, mutect2
- UBA2 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1338145844, COSV55830693, COSV55830918; called by muse, mutect2, varscan2
- UBQLNL | c.630A>C p.E210D | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66494639, COSV66494802; called by muse, mutect2, varscan2
- UNC5B | c.924G>A p.W308* | Nonsense Mutation (SNP) | VAF 7/89 reads (8%) | catalogued as COSV58981402; called by muse, mutect2
- UNC79 | c.6352G>A p.D2118N (on ENST00000393151 / NM_001346218.2; = p.D1941N on NM_020818.5) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56411484; called by muse, mutect2
- USP34 | c.8077C>T p.P2693S | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68406744; called by muse, mutect2
- USP34 | c.1731T>G p.S577R | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.962); catalogued as COSV101277128; called by muse, mutect2
- VWA3B | c.1275A>C p.K425N | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV68246853; called by muse, mutect2, varscan2
- WDR17 | c.3434C>T p.T1145I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54584228; called by mutect2, varscan2
- XDH | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV65151203; called by muse, mutect2, varscan2
- XKR3 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV58887982; called by muse, mutect2, varscan2
- XYLT2 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.517); catalogued as COSV50016719, COSV50022278; called by muse, varscan2
- YLPM1 | c.4252G>A p.E1418K | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); catalogued as COSV53120665; called by muse, mutect2
- ZBBX | c.1298A>C p.K433T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV56801717; called by muse, mutect2, varscan2
- ZBTB20 | c.530C>T p.A177V (on ENST00000474710 / NM_001164342.2; = p.A104V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61869725; called by muse, mutect2, varscan2
- ZDBF2 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV65630106; called by mutect2, varscan2
- ZFP2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.705); catalogued as rs1437594015, COSV63726934, COSV63727065; called by muse, mutect2, varscan2
- ZIM3 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV54144204; called by muse, mutect2, varscan2
- ZKSCAN5 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV58744628; called by muse, mutect2, varscan2
- ZNF112 | c.418C>T p.L140F (on ENST00000337401 / NM_001083335.2; = p.L134F on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs375974189; called by muse, mutect2, varscan2
- ZNF189 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as rs772358793, COSV52274579; called by muse, mutect2, varscan2
- ZNF212 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs753209975, COSV60026224; called by muse, mutect2, varscan2
- ZNF214 | c.1642C>T p.H548Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53483767; called by muse, mutect2, varscan2
- ZNF229 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.144); catalogued as COSV52164998; called by muse, mutect2, varscan2
- ZNF280A | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.406); catalogued as rs1183774995, COSV57482356; called by muse, mutect2, varscan2
- ZNF285 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV58411130, COSV58411330; called by muse, mutect2, varscan2
- ZNF536 | c.2767G>A p.D923N | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as rs140654011, COSV62821697; called by muse, mutect2, varscan2
- ZNF649 | c.1156A>T p.K386* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100031175; called by muse, mutect2, varscan2
- ZNF667 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs774142912, COSV52631256; called by muse, mutect2, varscan2
- ZNF676 | c.610G>A p.E204K (on ENST00000650058; = p.E172K on NM_001001411.3) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.279); catalogued as COSV68095021; called by muse, mutect2, varscan2
- ZNF831 | c.3583C>T p.P1195S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100926151; called by muse, mutect2, varscan2
- ZNF831 | c.3584C>T p.P1195L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1455915116, COSV100926152; called by muse, mutect2, varscan2
- AJAP1 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- ASAH2 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- CGB8 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- DDX3X | c.1966dup p.V656Gfs*2 (on ENST00000399959; = p.V657Gfs*2 on NM_001356.5) | Frame Shift Ins (INS) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- ENTPD7 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.074); called by muse, varscan2
- FCGBP | c.5297C>T p.S1766F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- IGKV4-1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 60/93 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- IGKV6D-21 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 126/502 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- TADA2A | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TRAV12-2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRAV19 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- TRBV3-1 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AACS | c.1698G>A p.V566= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV55540539; called by mutect2, varscan2
- ABI3BP | c.714G>A p.R238= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99427912; called by muse, mutect2, varscan2
- ADAM2 | c.912G>A p.L304= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV55868542; called by muse, mutect2, varscan2
- ADARB2 | c.1098C>T p.S366= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV67223475, COSV67237777; called by muse, mutect2, varscan2
- ADGRB1 | c.3255C>T p.L1085= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV60103518; called by muse, mutect2, varscan2
- ADORA1 | c.885C>T p.F295= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV55144304; called by muse, mutect2, varscan2
- AHCYL2 | c.1248C>T p.S416= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV61490064; called by muse, mutect2, varscan2
- ALKAL1 | c.198C>T p.F66= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV62131338; called by muse, mutect2
- ALMS1 | c.6924C>A p.S2308= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV52522327; called by muse, mutect2, varscan2
- ANGPT4 | c.840C>T p.F280= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV67922898; called by muse, mutect2, varscan2
- ANKRD2 | c.951G>A p.T317= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs752139699, COSV53969686; called by mutect2, varscan2
- ANKRD45 | c.225C>T p.I75= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs750768844, COSV60962629; called by muse, mutect2, varscan2
- ARHGAP17 | c.1743C>T p.D581= (on ENST00000289968 / NM_001006634.3; = p.D503= on NM_018054.6) | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1161178246, COSV51512235; called by muse, mutect2, varscan2
- ARHGAP21 | c.2046C>T p.S682= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV57611174; called by muse, mutect2, varscan2
- ARID4A | c.1101A>G p.Q367= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV62166730; called by muse, mutect2, varscan2
- ARNT | c.909C>T p.F303= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs146538917; called by muse, mutect2, varscan2
- ASTN1 | c.3342G>A p.L1114= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV62506730; called by muse, mutect2
- ATP13A5 | c.1929C>T p.F643= | Silent (SNP) | VAF 37/141 reads (26%) | catalogued as rs865991586, COSV60872697, COSV60874815; called by muse, mutect2, varscan2
- BAG4 | c.954C>T p.V318= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV54862619; called by muse, mutect2, varscan2
- BCL11A | c.2013G>A p.E671= (on ENST00000335712 / NM_001365609.1; = p.E705= on NM_018014.4) | Silent (SNP) | VAF 110/254 reads (43%) | catalogued as rs1330448134, COSV59637108; called by muse, mutect2, varscan2
- BDKRB1 | c.823T>C p.L275= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV53707330; called by muse, mutect2, varscan2
- BSN | c.2118A>G p.E706= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV56527843; called by muse, mutect2, varscan2
- BSN | c.8070C>T p.I2690= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs756227771, COSV56527854; called by muse, mutect2, varscan2
- C7 | c.660G>A p.R220= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV57481206; called by muse, mutect2, varscan2
- CA6 | c.495C>T p.F165= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as rs1366948886, COSV66261367; called by muse, mutect2, varscan2
- CBLN1 | c.120C>T p.S40= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV54655090; called by muse, mutect2, varscan2
- CBY2 | c.384C>T p.F128= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV60117881; called by muse, mutect2, varscan2
- CCDC148 | c.1428C>T p.A476= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs747581357, COSV51770869; called by muse, mutect2, varscan2
- CCDC60 | c.1071C>T p.S357= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV59550718; called by muse, mutect2, varscan2
- CCP110 | c.906C>T p.L302= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1446571223, COSV66818187; called by muse, mutect2, varscan2
- CCR5 | c.684G>A p.K228= | Silent (SNP) | VAF 28/258 reads (11%) | catalogued as rs1445636663, COSV52753097; called by muse, mutect2, varscan2
- CES3 | c.1554C>T p.P518= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV57593209; called by muse, varscan2
- CFAP70 | c.1251G>A p.V417= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV60286705; called by muse, mutect2, varscan2
- CLN3 | c.789C>T p.P263= (on ENST00000360019 / NM_001286104.2; = p.P287= on NM_000086.2) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1057524528, COSV61107852; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNGA2 | c.697C>T p.L233= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1234066244, COSV61706341; called by muse, mutect2, varscan2
- CNKSR1 | c.1533C>T p.P511= (on ENST00000374253 / NM_001297647.2; = p.P504= on NM_006314.3) | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs1229433663, COSV58794718; called by muse, mutect2, varscan2
- COL28A1 | c.156C>T p.I52= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs370084753; called by muse, mutect2, varscan2
- COL6A3 | c.7626C>T p.F2542= | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as rs758039484, COSV55110469; called by muse, mutect2, varscan2
- COL6A6 | c.3867G>A p.Q1289= | Silent (SNP) | VAF 29/181 reads (16%) | catalogued as COSV62038073; called by muse, mutect2, varscan2
- CORO2B | c.1263C>T p.V421= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV55957513; called by muse, mutect2, varscan2
- CPS1 | c.4266C>T p.S1422= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs1389889942, COSV51820649, COSV51824494; called by muse, mutect2, varscan2
- CRB1 | c.714T>G p.T238= | Silent (SNP) | VAF 27/177 reads (15%) | catalogued as COSV66348877; called by muse, mutect2, varscan2
- CREB3L3 | c.552C>T p.L184= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV50270173; called by muse, mutect2, varscan2
- CTTNBP2NL | c.951T>C p.F317= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as COSV54746955; called by muse, mutect2, varscan2
- CXCL10 | c.114A>G p.Q38= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV60661362; called by muse, mutect2, varscan2
- DDX23 | c.2091A>T p.G697= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV104396320, COSV56399630, COSV56400942; called by muse, mutect2, varscan2
- DDX49 | c.1020C>T p.A340= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55358879; called by muse, mutect2
- DHX57 | c.2787C>T p.I929= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs779273882, COSV99769762; called by muse, mutect2, varscan2
- DIAPH1 | c.1609C>T p.L537= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV53888844; called by muse, mutect2, varscan2
- DICER1 | c.2796C>T p.I932= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs1060504967, COSV58625593; ClinVar: likely benign; called by muse, mutect2, varscan2
- DLGAP3 | c.2106C>T p.A702= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV52397754; called by muse, mutect2, varscan2
- DLK1 | c.1107C>T p.I369= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs12975, COSV57991914; called by muse, mutect2, varscan2
- DMBT1 | c.6258G>A p.G2086= (on ENST00000338354 / NM_001377530.1; = p.G1329= on NM_004406.3) | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as COSV57562835; called by muse, mutect2
- DNAH7 | c.4767C>T p.S1589= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs377557458; called by mutect2, varscan2
- DNAH9 | c.5667C>T p.I1889= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV52377345; called by muse, mutect2, varscan2
- DNMT1 | c.4021C>T p.L1341= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV61583980; called by muse, mutect2, varscan2
- DRD1 | c.1107G>A p.A369= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as rs374239045; called by muse, mutect2, varscan2
- DRGX | c.387G>A p.K129= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV65137623; called by muse, mutect2
- DSCAML1 | c.2073G>A p.R691= (on ENST00000321322; = p.R631= on NM_020693.4) | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs566861272, COSV58402954; called by muse, mutect2, varscan2
- DYSF | c.5295G>A p.V1765= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV50268079; called by muse, mutect2, varscan2
- EBF3 | c.1224C>T p.I408= (on ENST00000355311 / NM_001375392.1; = p.I399= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs376451705; called by muse, mutect2, varscan2
- EEPD1 | c.396C>T p.P132= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV54203308; called by muse, mutect2, varscan2
- ENOSF1 | c.1074C>T p.F358= (on ENST00000340116 / NM_001354066.2; = p.F324= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV51895713; called by muse, mutect2, varscan2
- EYA2 | c.648C>T p.S216= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs367734889; called by muse, mutect2, varscan2
- FAIM2 | c.33G>A p.K11= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1357203768, COSV57741181; called by muse, mutect2
- FAM47B | c.282G>A p.K94= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV61456796; called by muse, mutect2, varscan2
- FAM50B | c.444G>A p.V148= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs1561775715, COSV66655280; called by muse, mutect2, varscan2
- FAM71D | c.687G>A p.R229= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs932899456, COSV61296690; called by muse, mutect2, varscan2
- FANK1 | c.843C>T p.P281= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV64137336; called by muse, mutect2, varscan2
- FAT3 | c.1533C>T p.I511= | Silent (SNP) | VAF 109/401 reads (27%) | catalogued as rs778023453, COSV53175104; called by muse, mutect2, varscan2
- FBXO15 | c.345C>T p.I115= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs775099298, COSV54044170; called by mutect2, varscan2
- FCRL1 | c.180C>T p.A60= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV63827004; called by muse, mutect2, varscan2
- FLG | c.10599G>A p.R3533= | Silent (SNP) | VAF 58/215 reads (27%) | catalogued as COSV64240679; called by muse, mutect2, varscan2
- FLNB | c.7386C>T p.I2462= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs753695923, COSV55895837; called by mutect2, varscan2
- FNDC7 | c.1932C>T p.I644= | Silent (SNP) | VAF 43/196 reads (22%) | catalogued as COSV54758125; called by muse, mutect2, varscan2
- FRYL | c.3456C>T p.G1152= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV51962712; called by muse, mutect2
- GALNT14 | c.1599C>T p.I533= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as rs774070861, COSV61103357; called by mutect2, varscan2
- GCC1 | c.612G>A p.A204= | Silent (SNP) | VAF 23/140 reads (16%) | catalogued as rs778780245, COSV50002069; called by muse, mutect2, varscan2
- GFPT2 | c.2013C>T p.F671= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV53812643; called by muse, mutect2, varscan2
- GHR | c.1269C>T p.L423= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV50131719; called by muse, mutect2, varscan2
- GPC2 | c.486C>T p.T162= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV52786588; called by muse, mutect2, varscan2
- GPR179 | c.3243G>A p.Q1081= (on ENST00000621958; = p.Q1080= on NM_001004334.4) | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- GRM7 | c.2346G>A p.E782= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs367971673, COSV63171788; called by mutect2, varscan2
- H2BC9 | c.276C>T p.S92= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV55100984; called by muse, mutect2, varscan2
- HMCN1 | c.5286C>T p.P1762= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs1278451813, COSV54942415; called by muse, mutect2, varscan2
- HPX | c.987C>T p.F329= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV56420667; called by muse, mutect2, varscan2
- HYDIN | c.4453C>T p.L1485= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV101143492, COSV66834441; called by mutect2, varscan2
- IGF1R | c.3975C>T p.A1325= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs70958400; called by muse, mutect2, varscan2
- IGHV3-30 | c.313C>T p.L105= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as rs768855678; called by muse, mutect2, varscan2
- IGHV4-59 | c.138C>T p.G46= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs1555554549; called by muse, mutect2, varscan2
- IGKV1D-8 | c.279C>T p.F93= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs1321248600; called by muse, mutect2
- IGKV2D-24 | c.129C>T p.F43= | Silent (SNP) | VAF 145/236 reads (61%) | called by muse, mutect2, varscan2
- IGKV3D-20 | c.39C>G p.L13= | Silent (SNP) | VAF 91/455 reads (20%) | called by muse, mutect2, varscan2
- ILVBL | c.693C>T p.G231= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV54622566; called by muse, mutect2, varscan2
- IMPA2 | c.837G>A p.T279= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs754917132, COSV52319251; called by muse, mutect2, varscan2
- IRAG1 | c.2154C>T p.S718= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV70209829; called by muse, mutect2, varscan2
- ITGA1 | c.777G>A p.K259= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV50899115; called by muse, mutect2, varscan2
- ITGA4 | c.2700C>T p.F900= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV67896202, COSV67897889; called by muse, mutect2, varscan2
- KCNA6 | c.597C>T p.F199= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV54976595; called by mutect2, varscan2
- KCNK17 | c.777C>T p.I259= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV64685889; called by muse, mutect2
- KCNMB2 | c.402G>A p.E134= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV64202118; called by muse, mutect2, varscan2
- KCNS3 | c.1341G>T p.R447= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100411334; called by muse, mutect2
- KIAA1755 | c.1866C>T p.I622= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs138852455; called by muse, mutect2, varscan2
- KIF13B | c.492C>T p.P164= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as COSV72962240; called by muse, mutect2, varscan2
- KIF21B | c.276G>A p.G92= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs150839616, COSV59757748; called by muse, mutect2, varscan2
- KIF26A | c.777C>T p.V259= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1488403741, COSV59470650; called by muse, varscan2
- KIF4B | c.114G>A p.E38= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV70531618; called by muse, mutect2, varscan2
- KIR3DL3 | c.867G>A p.G289= | Silent (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
- KLKB1 | c.1222C>T p.L408= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV52996410; called by muse, mutect2
- KRT74 | c.1095C>T p.I365= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV59771157; called by muse, mutect2, varscan2
- LAMA4 | c.3090C>T p.S1030= (on ENST00000230538 / NM_001105206.3; = p.S1023= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV100038959; called by muse, mutect2, varscan2
- LCT | c.243C>T p.A81= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99919269; called by muse, mutect2, varscan2
- LIMD1 | c.402C>T p.S134= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV56270446; called by muse, mutect2, varscan2
- LPIN1 | c.1107C>T p.A369= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV56770820; called by muse, mutect2, varscan2
- LRIT2 | c.1617G>A p.G539= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as rs1468550678, COSV60566483; called by muse, mutect2
- LRRC7 | c.3195C>T p.V1065= (on ENST00000651989 / NM_001370785.2; = p.V1032= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV50447896, COSV50630959; called by muse, mutect2, varscan2
- LRRC8A | c.1180C>T p.L394= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV52189366, COSV99396468; called by muse, mutect2, varscan2
- LRRK2 | c.4164C>T p.L1388= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs757255377, COSV54171122; called by mutect2, varscan2
- MATN2 | c.513G>A p.G171= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs757051210, COSV54719211, COSV54719561; called by muse, mutect2, varscan2
- MCTP1 | c.1131C>T p.L377= | Silent (SNP) | VAF 51/188 reads (27%) | catalogued as COSV56533986; called by muse, mutect2, varscan2
- MDGA1 | c.2706G>A p.G902= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99776779; called by muse, mutect2, varscan2
- MECOM | c.2550C>T p.F850= (on ENST00000468789 / NM_001105078.4; = p.F1038= on NM_004991.4) | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs866698177, COSV52959810, COSV99245276; called by muse, mutect2, varscan2
- METTL9 | c.438C>T p.T146= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs368363411; called by muse, mutect2, varscan2
- MGST3 | c.276C>A p.A92= | Silent (SNP) | VAF 44/203 reads (22%) | catalogued as COSV63321776; called by muse, mutect2, varscan2
- MMP2 | c.403C>T p.L135= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV54605370; called by muse, mutect2, varscan2
- MMRN1 | c.1836G>A p.E612= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV53334521, COSV53341876; called by muse, mutect2, varscan2
- MOV10L1 | c.384G>A p.V128= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs763939565, COSV53179431; called by muse, mutect2, varscan2
- MPDZ | c.3303G>A p.L1101= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100057260; called by muse, mutect2, varscan2
- MROH7 | c.3297C>T p.V1099= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs190299683; called by mutect2, varscan2
- MROH7 | c.3825C>T p.S1275= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV64888370; called by muse, mutect2, varscan2
- MUC16 | c.12750G>A p.T4250= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs918205385, COSV67470997; called by muse, mutect2, varscan2
- MYBBP1A | c.712C>T p.L238= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV54604572; called by muse, mutect2, varscan2
- MYH7 | c.3279G>A p.R1093= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs1438305998, COSV62523987; called by muse, mutect2, varscan2
- MYLK4 | c.510C>T p.F170= | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as rs751431948, COSV51143670; called by muse, mutect2, varscan2
- MYO18B | c.4728G>A p.R1576= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1257038016, COSV59135018; called by muse, mutect2, varscan2
- MYO1A | c.2535G>A p.R845= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs1167060924, COSV55657418; called by muse, mutect2, varscan2
- MYOM3 | c.3894G>A p.G1298= | Silent (SNP) | VAF 27/193 reads (14%) | catalogued as COSV58401129; called by muse, mutect2, varscan2
- NFKB2 | c.126C>T p.I42= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs976488499, COSV51870843, COSV51874273; called by muse, mutect2, varscan2
- NOBOX | c.336G>A p.E112= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV56197858, COSV99779876; called by muse, mutect2, varscan2
- NOS3 | c.1410C>T p.S470= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs759701069, COSV52495849; called by muse, mutect2, varscan2
- NUGGC | c.1854G>A p.G618= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV58439164; called by muse, mutect2, varscan2
- NUP210L | c.2961G>A p.E987= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV55158022, COSV99667558; called by muse, mutect2, varscan2
- OBI1 | c.807C>T p.S269= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV56147525; called by muse, mutect2, varscan2
- OLA1 | c.501A>G p.L167= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs1337016204, COSV52974304; called by muse, mutect2, varscan2
- OOEP | c.198C>T p.D66= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV64859561; called by muse, mutect2, varscan2
- OPRL1 | c.69C>T p.S23= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV61092964; called by muse, mutect2, varscan2
- OR10G4 | c.489C>T p.F163= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV100304893, COSV57979018; called by muse, varscan2
- OR10G9 | c.768C>T p.F256= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV66685830; called by muse, mutect2, varscan2
- OR2A5 | c.729C>T p.S243= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV68738757; called by muse, varscan2
- OR2D3 | c.147C>T p.I49= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV58574033; called by mutect2, varscan2
- OR5A2 | c.933G>A p.G311= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV57390344, COSV57391934; called by muse, mutect2, varscan2
- OR5C1 | c.675C>T p.I225= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs762811453, COSV65456169; called by muse, mutect2, varscan2
- OR6B1 | c.747C>T p.F249= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV68770669; called by muse, mutect2, varscan2
- OR6B3 | c.12G>A p.E4= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV60116531; called by muse, mutect2
- OR6C2 | c.696G>A p.R232= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV59516961; called by muse, mutect2, varscan2
- PAK3 | c.66C>T p.N22= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99457925; called by muse, mutect2, varscan2
- PAK5 | c.2082C>T p.L694= | Silent (SNP) | VAF 33/190 reads (17%) | catalogued as COSV62025697, COSV62038153; called by muse, mutect2, varscan2
- PAPPA | c.1266G>A p.E422= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs886670198, COSV60292093; called by muse, mutect2, varscan2
- PCDH8 | c.2904C>T p.S968= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100131922; called by muse, varscan2
- PCDHA6 | c.1284G>A p.R428= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as COSV67071774; called by muse, mutect2, varscan2
- PCLO | c.5235G>A p.P1745= | Silent (SNP) | VAF 11/181 reads (6%) | catalogued as rs967947107, COSV61615072; called by muse, mutect2
- PCLO | c.4485G>A p.E1495= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV61666943; called by muse, varscan2
- PGLYRP3 | c.972C>T p.S324= | Silent (SNP) | VAF 65/239 reads (27%) | catalogued as rs756935845, COSV51952015; called by muse, mutect2, varscan2
- PKLR | c.999C>T p.I333= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV61362550; called by muse, mutect2, varscan2
- PLCB3 | c.627C>T p.S209= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV54192399; called by muse, mutect2, varscan2
- PLCB4 | c.813C>T p.I271= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV53804853; called by muse, mutect2, varscan2
- PLCL1 | c.861C>T p.I287= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV101406846, COSV70875170; called by muse, mutect2, varscan2
- PLD5 | c.675C>T p.I225= (on ENST00000442594; = p.I163= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs753605572, COSV59135418; called by muse, mutect2, varscan2
- PLXNA4 | c.5313C>T p.L1771= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV58160793; called by muse, mutect2
- PLXNA4 | c.573G>A p.G191= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs267601296, COSV58160813; called by muse, mutect2, varscan2
- PNMA5 | c.318G>A p.L106= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV62626289; called by muse, mutect2, varscan2
- PPP2CA | c.115C>T p.L39= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV51539163; called by muse, mutect2, varscan2
- PRAMEF15 | c.252C>T p.L84= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs1168284840; called by muse, varscan2
- PRAMEF2 | c.375C>T p.F125= | Silent (SNP) | VAF 67/333 reads (20%) | catalogued as rs1188397790, COSV53576237; called by muse, mutect2, varscan2
- PRAMEF20 | c.153C>T p.A51= | Silent (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.1044C>T p.L348= (on ENST00000295902; = p.L292= on NM_198859.4) | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV55771903; called by muse, mutect2, varscan2
- PRKACG | c.672C>T p.A224= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV55258022; called by muse, mutect2, varscan2
- PRKG1 | c.1683C>T p.I561= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV64778185; called by muse, mutect2, varscan2
- PRPS1L1 | c.742T>C p.L248= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs909564064, COSV72650019; called by muse, mutect2, varscan2
- PRRG2 | c.219C>T p.S73= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV55869907; called by muse, mutect2, varscan2
- PSD4 | c.1935C>T p.A645= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV55530363; called by muse, mutect2
- PSMB1 | c.414C>T p.I138= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs202191704; called by muse, mutect2, varscan2
- PTAFR | c.265C>T p.L89= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs1285890108, COSV59538360; called by muse, mutect2, varscan2
- PTPN14 | c.1800G>A p.R600= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV65288652; called by muse, mutect2, varscan2
- PTPRK | c.969C>T p.I323= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV63888643; called by muse, mutect2, varscan2
- PUS3 | c.105T>C p.N35= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV57104970; called by muse, mutect2, varscan2
- PWWP3B | c.93G>A p.R31= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs750656598, COSV61798580, COSV61801209; called by muse, mutect2
- PYROXD2 | c.1314C>T p.I438= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV65331501; called by muse, mutect2
- PZP | c.1347C>T p.S449= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV54370615; called by muse, mutect2, varscan2
- QSOX1 | c.1659G>A p.R553= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV62581347; called by muse, mutect2, varscan2
- RENBP | c.1149G>A p.K383= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100892455; called by muse, mutect2, varscan2
- RHPN1 | c.1968G>A p.V656= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV56649638; called by muse, mutect2, varscan2
- RNF122 | c.156C>T p.S52= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs1460641245, COSV56360061; called by muse, mutect2
- ROBO2 | c.3141G>A p.G1047= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs752185497, COSV59939538; called by mutect2, varscan2
- RYR3 | c.9693G>A p.E3231= (on ENST00000389232; = p.E3232= on NM_001036.6) | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV101213375; called by muse, mutect2, varscan2
- RYR3 | c.12519G>A p.K4173= (on ENST00000389232; = p.K4174= on NM_001036.6) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs771105584, COSV66807809, COSV66808884; called by muse, mutect2, varscan2
- SCG5 | c.78T>C p.A26= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs1430601888, COSV100276878; called by muse, mutect2, varscan2
- SCN11A | c.2256G>A p.G752= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV56578569; called by muse, mutect2, varscan2
- SCN9A | c.573G>A p.L191= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV57624685; called by muse, mutect2, varscan2
- SCRN1 | c.516G>A p.G172= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV54134193; called by muse, mutect2, varscan2
- SEC31B | c.1230G>A p.L410= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs1405390264, COSV100944872, COSV64825173; called by muse, mutect2, varscan2
- SERPINB7 | c.606G>A p.G202= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV60535055; called by muse, mutect2
- SERPINE1 | c.177C>T p.P59= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1484797771, COSV56171559; called by muse, mutect2, varscan2
- SIM2 | c.627G>A p.G209= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as COSV51773026; called by muse, mutect2
- SLC14A2 | c.1228C>T p.L410= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV54914651; called by muse, mutect2, varscan2
- SLC16A14 | c.885G>A p.K295= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV54621420; called by muse, mutect2, varscan2
- SLC35G5 | c.243C>T p.L81= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as rs776516733, COSV55312101; called by muse, mutect2, varscan2
- SLC4A1 | c.1479C>T p.I493= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs867700459, COSV52263216; called by muse, mutect2, varscan2
- SLC6A17 | c.732G>A p.K244= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs763398547, COSV58996960; called by muse, mutect2, varscan2
- SLFN11 | c.180G>A p.V60= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV57700581; called by muse, mutect2, varscan2
- SLITRK1 | c.636C>T p.N212= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV65676740; called by mutect2, varscan2
- SMARCA1 | c.3165A>G p.*1055= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs377501295, COSV100946647; called by muse, mutect2, varscan2
- SPRR1B | c.102C>T p.I34= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs1412394316, COSV61068101; called by muse, mutect2, varscan2
- SPTAN1 | c.4338A>G p.E1446= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV63989880; called by muse, mutect2, varscan2
- SREBF2 | c.1488C>T p.P496= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as rs146289041; called by muse, mutect2, varscan2
- ST14 | c.546C>T p.P182= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs769666753, COSV99598974; called by muse, mutect2, varscan2
- ST6GAL2 | c.1095C>T p.V365= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as rs1338278043, COSV62418162; called by muse, mutect2
- STEAP2 | c.561C>T p.F187= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV55293802; called by muse, mutect2, varscan2
- STK31 | c.2091G>A p.Q697= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as COSV63459557; called by muse, mutect2, varscan2
- SVEP1 | c.7749C>T p.F2583= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs777938125, COSV52844276; called by muse, mutect2, varscan2
- TACC3 | c.570C>T p.S190= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs1199715367, COSV57608083; called by muse, mutect2, varscan2
- TC2N | c.606G>A p.R202= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs1029229623, COSV61748266; called by muse, mutect2, varscan2
- TDRD5 | c.2649C>T p.P883= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV54250676; called by muse, mutect2
- TENM1 | c.3144G>A p.T1048= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs763660900, COSV64424110; called by muse, mutect2, varscan2
- TGM2 | c.24G>A p.E8= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV63932473; called by muse, mutect2, varscan2
- TM4SF1 | c.348A>G p.A116= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs1269076377, COSV59525535; called by muse, mutect2, varscan2
- TNFSF13B | c.111C>T p.P37= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV65517227; called by muse, mutect2, varscan2
- TOP3A | c.2538C>T p.F846= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV58181138; called by muse, mutect2, varscan2
- TOX4 | c.1323C>G p.P441= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV52971345; called by muse, mutect2, varscan2
- TRANK1 | c.2190G>A p.P730= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs371331632; called by muse, mutect2, varscan2
- TRAV39 | c.174G>A p.G58= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- TRBV3-1 | c.297C>T p.S99= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- TRPC7 | c.9G>A p.R3= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs745955629, COSV100725747, COSV61458108; called by muse, mutect2, varscan2
- TTN | c.19722G>A p.K6574= (on ENST00000591111; = p.K5647= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs1371108599, COSV100622475; called by muse, mutect2, varscan2
- TTN | c.8661C>T p.T2887= (on ENST00000591111; = p.T2841= on NM_003319.4) | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV60354999; called by muse, mutect2
- UBN2 | c.2454C>T p.P818= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV56035517; called by muse, mutect2, varscan2
- USP22 | c.612C>T p.F204= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV54949068; called by muse, mutect2, varscan2
- VANGL1 | c.1245G>A p.Q415= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV59622450; called by muse, mutect2, varscan2
- VCAN | c.1737C>T p.V579= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs780629672, COSV54116932; called by muse, mutect2, varscan2
- VIPR1 | c.894G>A p.K298= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV57298868; called by muse, mutect2, varscan2
- VPS13D | c.1353G>T p.G451= | Silent (SNP) | VAF 47/206 reads (23%) | catalogued as COSV62534552; called by muse, mutect2, varscan2
- WFDC3 | c.216G>A p.R72= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV54786370; called by muse, mutect2, varscan2
- XYLT1 | c.2181C>T p.I727= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as rs112238716; called by muse, mutect2
- ZAN | c.2736A>G p.K912= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV61816743; called by muse, varscan2
- ZFAT | c.414C>T p.I138= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs200807830, COSV64734748; called by muse, mutect2, varscan2
- ZMYND8 | c.3012C>T p.I1004= (on ENST00000311275 / NM_001363741.2; = p.I978= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as rs1221692469, COSV53685751; called by muse, mutect2, varscan2
- ZNF107 | c.1944C>T p.S648= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV61332120; called by muse, mutect2, varscan2
22 further variants in this file (0 protein-altering or splice-affecting, 5 silent, 17 other) are not listed here.
